CCDI case PBCLPD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/06c5c891-3da8-4016-8368-61ba9414ed71

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.3 years (9,236 days).

Biospecimens (3 samples)
- Sample 0DVZ0K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZ0W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVZ1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
